Gene-level copy-number profile of tumor specimen ALCH-B05W-TTP1-A from ALCHEMIST case ALCH-B05W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,187 days).
Specimen ALCH-B05W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5720065-7eac-495a-8962-dd63e15b5d8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B05W-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/5f8c67f5-c098-4a7f-a76b-2ea2dc181c75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 7,464; copy number 2: 42,302; copy number 3: 7,916; copy number 4: 613; copy number 5: 13; copy number 6: 4; copy number 7: 1; copy number 8: 1; copy number 11: 1; copy number 14: 3; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:203,238,977–203,315,871, 3 genes (within-gene range 0–2): CYP20A1, RN7SL670P, MRPL50P2.
- chr2:203,328,459–203,329,226, 1 gene (within-gene range 0–2): AC080075.1.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr10:17,602,910–17,603,127, 1 gene (within-gene range 0–2): AC069542.2.
- chr15:25,172,635–25,239,919, 37 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38.
- chr15:34,520,608–34,588,503, 4 genes: DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr15:77,784,610–77,788,674, 2 genes (within-gene range 0–2): AC105133.2, AC105133.1.
- chr16:32,388,135–32,436,203, 1 gene: AC138915.2.
- chr16:32,715,931–32,788,944, 8 genes: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–1): AC092143.1, AC092143.2, TUBB3.
- chr17:67,019,934–67,033,290, 2 genes (within-gene range 0–3): AC005544.1, AC005544.2.
- chr17:81,939,645–81,947,601, 2 genes (within-gene range 0–3): MYADML2, AC145207.1.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–2): AC090386.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr11:89,883,927–89,900,449, 3 genes, copy number 5–6: AP005435.4, AP005435.2, AP005435.3.
- chr11:90,017,611–90,042,025, 2 genes, copy number 5: AP004607.6, TRIM49C.
- chr12:53,210,567–53,232,980, 1 gene, copy number 7: RARG.
- chr16:18,357,026–18,379,410, 3 genes, copy number 14: AC126755.4, NPIPA9, MIR6770-3.
- chr16:32,356,981–32,380,049, 2 genes, copy number 5: AC133548.1, ACTR3BP3.
- chr17:2,049,908–2,063,241, 3 genes, copy number 6 (within-gene range 1–6): MIR132, MIR212, HIC1.
- chr17:18,426,861–18,431,848, 1 gene, copy number 11: KRT17P2.
- chr17:18,476,737–18,494,945, 1 gene, copy number 18: LGALS9C.
- chr17:79,778,148–79,839,440, 5 genes, copy number 5: CBX2, CBX8, AC100791.2, LINC01977, CBX4.
- chr19:58,305,319–58,315,663, 1 gene, copy number 5 (within-gene range 2–5): ERVK3-1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.

Autosomal genes at a single copy (total copy number 1): 5,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
